Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A7P0, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A7P0-01A (Primary Tumor).

[page 1 of 6]
years Sex: Male

Date Printed:
Date Collected :
Date Received:
Accession No:
Physician:
Copy to:

Surgical Pathology Report

Clinical Information

year old male patient presents for radical pleurectomy and PDT for mesothelioma.

ICD-O-3
Mesothelioma, epithelioid NOS
9052/3
Site Pleura, NOS
C38.4
JAS 9/24/13

Final Diagnosis

1. PREVIOUS INCISION SITE, FROZEN SECTION:

Skin and underlying soft tissue with changes of previous biopsy site and scar formation, no tumor seen.

2. RIB:

Benign lamellar bone with trilinear bone marrow formation and surrounding soft tissue with foreign body type giant cell formation consistent with close previous biopsy site.

3. PARIETAL PLEURA, FROZEN SECTION:

Dense fibrocollagenous soft tissue with focal chronic and acute inflammation.
No tumor seen.

4. PARIETAL PLEURA:

Fragments of fibrofatty soft tissue with focal mesothelial lining.
No tumor seen.

5. LEVEL 6:

Sections of lymph node, no tumor seen.

6. PERICARDIAL FAT:

Fibrofatty soft tissue with mesothelial lining with focal areas of significant increased proliferation of mesothelial cells, suspicious of focal involvement by mesothelioma.

7. LEVEL 5:

Sections of lymph node, no tumor seen.

8. APICAL CHEST MASS, FROZEN SECTION:

Tumor nodule with presence of malignant mesothelioma, epithelioid type.

The tumor is present within the lung parenchyma and shows a focal presence of a pseudo capsule.

In other areas the tumor nodules are invading directly into alveolar lung parenchyma.

No tumor seen at stapled resection margin of specimen.

Tumor is positive for calretinin, CK7, D2-40 (focal), CK5/6 (focal), AE1-3 and negative for CD15, TTF1, CEA, MOC31 and WT1 consistent with the diagnosis of mesothelioma

9. PERIPHRENIC TISSUE:

Fibrofatty soft tissue with superficial mesothelial lining.

Name: [REDACTED]
MRN: [REDACTED]

[page 2 of 6]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected:
Date Received:
Accession No:
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

The mesothelial lining, shows, in areas, prominent proliferation and pleomorphism suspicious of focal involvement by malignant mesothelioma.
Prominent foreign body type giant cells identified.

10. LEVEL 9:

Fragments of fibrofatty soft tissue, no tumor seen.
Section of small lymph node, no tumor seen.

11. POSTERIOR INTERCOSTAL:

Sections of lymph node, no tumor seen.

12. VISCERAL PLEURA:

Sections of fibrous soft tissue with mesothelial lining and prominent giant cell formation.
The mesothelium is, in areas, prominently proliferative with pleomorphic changes suspicious for focal involvement with mesothelioma.

13. LEVEL 8:

Sections of lymph node, no tumor seen.

14. LEVEL 7:

Sections of lymph node, no tumor seen.
Fibrofatty soft tissue with accumulation of mesothelial cells not diagnostic for malignant tumor.

15. VISCERAL PLEURA (STITCH MARKS NODULE):

Sections of visceral pleura with prominent foreign body type giant cells and lined by mesothelium with focal prominent proliferation of mesothelium.
No definite tumor seen.

16. PHRENIC NODE:

Sections of lymph node, no tumor seen.

17. PERICARDIAL TISSUE:

Soft tissue with **presence of mesothelioma.**

18. DIAPHRAGMATIC PLEURA:

Fibrofatty soft tissue with focal mesothelial lining and focal mesothelial hyperplasia, no definite tumor seen.

Name: [REDACTED]
MRN: [REDACTED]

[page 3 of 6]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected
Date Received:
Accession No: [REDACTED]
Physician: Fric
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Selective slides reviewed with

The case material was reviewed and the report verified by:
(Electronic signature)
Verification Date:

Note

Disclaimer:

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide pathologists with adjunctive information to assist their morphologic evaluation. The tests using IUO or IUO reagents were developed and their performance characteristics were validated for diagnostic use by the

This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that is not directly confirmed by routine histopathologic internal or external control specimens.

Frozen Section Diagnosis

FS-1: Incision site: Skin and scar, no tumor seen.

FS-2: Parietal pleura: Fibrous tissue with surrounding reactive and atypical mesothelial cell proliferation. No definite invasive pattern seen. (Seen with

FS-3: Chest mass: No definite tumor seen at lung margin of specimen.

Gross Description

The specimens are received in eighteen parts labeled with the patient's name and medical record number.

Specimen #1 is received fresh for frozen section and labeled "previous incision site". The specimen consists of a 10.4 x 1.2 cm skin ellipse excised to a depth of 1.6 cm. The skin surface is tan grey, wrinkled and displays an ill defined linear scar which surfaces the entire length of the specimen. Representative sections are submitted for frozen section and the frozen section control is submitted in cassette 1A. Additional representative sections are submitted in cassette 1B.

Name: [REDACTED]
MRN: [REDACTED]

[page 4 of 6]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected:
Date Received:
Accession No.:
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #2 is received in formalin and labeled "rib". The specimen consists of three cylindrical portions of firm and trabeculated bone ranging from 5.6 cm to 6.0 cm in length and averaging 1.5 cm in greatest dimension. Sectioning reveals grossly unremarkable cut surfaces. No discrete masses or lesions are grossly identified.

A representative section is submitted in cassette 2A following decalcification.

Specimen #3 is received fresh for frozen section and labeled "parietal pleura". The specimen consists of a 1.1 x 0.6 x 0.3 cm irregular fragment of tan white to tan yellow, rubbery soft tissue which is submitted in toto in cassette 3A.

Specimen #4 is received in formalin and labeled "parietal pleura". The specimen consists of a 7.2 x 5.4 x 2.5 cm aggregate of multiple irregular and ragged fragments of grey purple to tan yellow, wrinkled soft tissue. Focal areas of muscle are identified. The outer surfaces are grossly unremarkable with no discrete masses or nodules identified.

Representative sections of muscle are submitted in cassette 4A.

Representative sections from the remainder of the specimen are submitted in cassettes 4B through 4D.

Specimen #5 is received in formalin and labeled "Level 6". The specimen consists of two tan grey to yellow tan, nodular soft tissue fragments measuring 0.6 cm and 1.0 cm in greatest dimension. The specimen is submitted in toto in cassette 5A.

Specimen #6 is received in formalin and labeled "pericardial fat". The specimen consists of four irregular fragments of tan yellow to grey purple, coarsely lobulated adipose tissue ranging from 2.4 cm to 6.5 cm in greatest dimension. Sectioning reveals two indurated, focally nodular areas measuring 0.5 cm and 0.6 cm in greatest dimension. The remaining cut surfaces are tan yellow and grossly unremarkable. The nodular areas are submitted entirely in cassette 6A.

Representative sections from the remainder of the specimen are submitted in cassette 6B.

Specimen #7 is received in formalin and labeled "Level 5". The specimen consists of a 2.8 x 2.4 x 1.0 cm nodular and indurated soft tissue fragment which is bisected and submitted entirely in cassettes 7A and 7B.

Specimen #8 is received fresh for frozen section and labeled "apical chest mass". The specimen consists of an 83 gram (following formalin fixation), 7.5 x 6.9 x 4.5 cm nodular soft tissue fragment which displays a 9.5 cm in length staple line along one aspect of the specimen. The specimen is incised at time of frozen section to reveal a 6.6 x 6.5 x 4.5 cm tan white, firm nodule which grossly abuts the visceral pleura. On one aspect of the nodule, there is a 5.5 x 4.5 x 1.5 cm focus of red brown, grossly unremarkable lung parenchyma attached.

The tissue adjacent to the stapled resection margin is submitted for frozen section and additional representative sections are submitted as follows:

Block 8A	Frozen section control
Block 8B	True resection margin
Blocks 8C,8D	Representative mass
Block 8E	Mass in relation to uninvolved lung parenchyma

Name: [REDACTED]
MRN: [REDACTED]

[page 5 of 6]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected:
Date Received:
Accession No.:
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #9 is received in formalin and labeled "periphrenic tissue". The specimen consists of two irregular and ragged fragments of grey purple to tan yellow, coarsely lobulated soft tissue measuring 7.9 cm and 16.8 cm in greatest dimension. Sectioning reveals grey purple to tan white, focally dense and fibrous cut surfaces with a large amount of yellow tan, coarsely lobulated adipose tissue. No discrete masses or nodules are grossly identified. Representative sections are submitted in cassettes 9A through 9C.

Specimen #10 is received in formalin and labeled "Level 9". The specimen consists of a 0.8 x 0.6 x 0.5 cm tan grey to tan yellow, nodular soft tissue fragment which is submitted in toto in cassette 10A.

Specimen #11 is received in formalin and labeled "posterior intercostal". The specimen consists of a 1.2 x 1.0 x 0.5 cm tan yellow nodular soft tissue fragment which is submitted in toto in cassette 11A.

Specimen #12 is received in formalin and labeled "visceral pleura". The specimen consists of two irregular and ragged fragments of grey purple, wrinkled soft tissue tissue. One of the fragments displays a 1.0 cm in greatest dimension indurated focus which is sectioned to reveal tan white to tan yellow, firm cut surfaces. The remaining fragments display a 0.7 cm stellate tan white focus of tissue. No other discrete masses or nodules are identified. The indurated nodular areas are submitted in cassettes 12A and 12B. Additional representative section is submitted in 12C.

Specimen #13 is received in formalin and labeled "Level 8". The specimen consists of a 0.9 x 0.8 x 0.5 cm tan grey, nodular soft tissue fragment which is submitted in toto in cassette 13A.

Specimen #14 is received in formalin and labeled "Level 7". The specimen consists of two grey tan to tan yellow, nodular soft tissue fragments measuring 1.0 cm and 1.1 cm in greatest dimension. The specimen is submitted in toto in one cassette labeled 14A.

Specimen #15 is received in formalin and labeled "visceral pleura, stitch marks nodule". The specimen consists of a 9.5 x 1.1 x 0.7 cm ragged and irregular fragment of grey purple, wrinkled and glistening soft tissue which has been oriented by the surgeon with a stitch denoting a 0.5 cm in greatest dimension tan white, indurated nodule. The remaining cut surfaces are grossly unremarkable with no discrete masses or lesions identified. On one aspect of the specimen is a 2.0 cm in greatest dimension focus of red brown, spongy possible lung parenchyma. The nodular area is submitted entirely in one cassette labeled 15A. Additional representative sections of the remainder of specimen submitted in cassettes 15B and 15C.

Specimen #16 is received in formalin and labeled "phrenic node". The specimen consists of two yellow tan, nodular soft tissue fragments measuring 1.0 cm and 1.2 cm in greatest dimension. The largest fragment is bisected and the specimen is submitted entirely in cassette 16A.

Name: [REDACTED]
MRN: [REDACTED]

[page 6 of 6]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #17 is received in formalin and labeled "pericardial tissue". The specimen consists of four irregular fragments of grey purple, wrinkled soft tissue ranging from 0.3 cm to 1.3 cm in greatest dimension. The specimen is submitted in toto in cassette 17A.

Specimen #18 is received in formalin and labeled "diaphragmatic pleura". The specimen consists of a 9.0 x 2.2 x 0.8 cm ragged and irregular strip of grey purple, wrinkled soft tissue which displays a 1.0 cm in greatest dimension area of induration which is sectioned to reveal tan white, dense cut surfaces. The area of induration is submitted entirely in cassette 18A. Additional representative sections are submitted in cassette 18B.

Dictated by:

Pathologist(s)

Name: [REDACTED]
MRN: [REDACTED]

Page 6 of 6

Source: NCI Genomic Data Commons file 3423c242-295e-47e1-b86e-e01a04f18eee (TCGA-TS-A7P0.887CA21D-BC50-446A-B804-98147E5604AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).